Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81K, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81K-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date:

Material: left adrenal

There is a tumor with a diameter of 5.5x5x3.3 cm.
Histologically, the tumor with an alveolar architecture composed with zellballen. These zellballen are separated by thin layers of connective tissue. Tumor cells have a relatively broad eosinophil to basophil granular cytoplasm. The nuclei are large and pleomorph with coarse chromatin. Often very large cells with bizarre and strongly enlarged nuclei are found. Single mitoses (1/30 HPF) are visible, one atypic mitosis was found. No evidence for necrosis, vessel invasion, capsule destruction or invasion into adjacent adipose tissue. With PAS staining, the total score sums up to 3

Final diagnosis: Pheochromocytoma

PASS-Score:

Total Score Score (max. 20) 3

Translated by:

ICD-O-3
Pheochromocytoma NOS 8700/8
Site @ Adrenal gland NOS C74.9
JAJ 10/17/13

Source: NCI Genomic Data Commons file 0988380d-6b43-457c-a6b0-dbf55469130e (TCGA-WB-A81K.5616B37A-5751-4067-8809-02B827F809F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).